Somatic mutation profile of tumor specimen TCGA-GS-A9TV-01A (aliquot TCGA-GS-A9TV-01A-11D-A382-10) from TCGA case TCGA-GS-A9TV, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mediastinal (thymic) large B-cell lymphoma; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 40.6 years (14,838 days).
Specimen TCGA-GS-A9TV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5383fa7-2c46-4a0d-be80-0170104a2856.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GS-A9TV-10A (Blood Derived Normal), aliquot TCGA-GS-A9TV-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bab6997-f6f1-4bbf-8c11-15077a86a0ad

The open-access MAF lists 61 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 42, Silent 14, Nonsense Mutation 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX3 | c.886C>A p.R296S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs1310416814, COSV100712083; called by muse, mutect2
- ADCY3 | c.3105C>A p.F1035L | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99569307; called by muse, mutect2
- AMELX | c.66T>A p.H22Q | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100499536; called by muse, mutect2
- AMER1 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.047); catalogued as COSV100367210; called by muse, mutect2
- ASXL3 | c.6397C>T p.P2133S | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV99327193; called by muse, mutect2
- ATG4A | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 33/465 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100565279; called by muse, mutect2
- CAPN7 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 21/444 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1030379002, COSV99513138; called by muse, mutect2
- CNTN5 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV99682776; called by muse, mutect2
- COPS3 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as rs767434942, COSV52004753, COSV52004791; called by muse, mutect2, varscan2
- DDX3X | c.922C>T p.Q308* (on ENST00000399959; = p.Q309* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 26/448 reads (6%) | catalogued as COSV67863459; called by muse, mutect2
- FAM120A | c.2308T>G p.S770A | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99466886; called by muse, mutect2
- FAM13C | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV53249848; called by muse, mutect2
- FBP2 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100942248; called by muse, mutect2, varscan2
- FBXO38 | c.2822T>C p.V941A (on ENST00000340253 / NM_205836.3; = p.V866A on NM_030793.5) | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99694161; called by muse, mutect2
- FSCB | c.32T>A p.I11K | Missense Mutation (SNP) | VAF 30/599 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100469022, COSV100470054; called by muse, mutect2
- GPR55 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1234989198, COSV67407671; called by muse, mutect2
- GRIN3A | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100701970; called by muse, mutect2
- HTATSF1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99511993; called by muse, mutect2
- IGLV3-9 | c.209G>C p.S70T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs111894401; called by muse, mutect2, varscan2
- IL13RA1 | c.1096T>A p.Y366N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100861598; called by muse, mutect2
- KAT2B | c.1775A>G p.H592R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99770054; called by muse, mutect2
- LIMD2 | c.207C>G p.H69Q | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV99368774; called by muse, mutect2
- NBR1 | c.1130A>G p.D377G | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100358055; called by muse, mutect2
- NCBP2L | c.439T>G p.F147V | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV100966536; called by muse, mutect2
- OGG1 | c.39T>G p.H13Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); catalogued as COSV100115688; called by muse, mutect2, varscan2
- OR1L3 | c.398T>G p.V133G | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100506277, COSV100506348; called by muse, mutect2
- OR4D10 | c.76G>C p.V26L | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV101597041; called by muse, mutect2
- PDLIM4 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99517058; called by muse, mutect2
- PLCB1 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV62044216; called by muse, mutect2
- PMPCB | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs759505735, COSV50785456; called by muse, mutect2
- PROKR1 | c.662G>A p.W221* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100375840; called by muse, mutect2
- RBM10 | c.2626G>A p.G876S | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100238451; called by muse, mutect2
- RFC4 | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs944896380, COSV56216791; called by muse, mutect2
- RNF19A | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100348248; called by muse, mutect2
- TECPR2 | c.1057A>G p.S353G | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as COSV100850265; called by muse, mutect2
- TMSB4X | c.14C>G p.P5R | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as COSV101020383, COSV66081775; called by muse, mutect2
- UACA | c.664A>G p.N222D | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100537892; called by muse, mutect2
- UNC13B | c.4009-1G>T p.X1337_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | catalogued as COSV101037547; called by muse, mutect2
- USH2A | c.2050C>A p.Q684K | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.192); catalogued as rs1206789266, COSV100244562; called by muse, mutect2
- WDR53 | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 31/621 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100218180; called by muse, mutect2
- ZNF217 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs369074794; called by muse, mutect2, varscan2
- ZNF607 | c.1968T>G p.S656R | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.098); catalogued as COSV100777988; called by muse, mutect2
- ZSCAN1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.699); catalogued as rs1409636598, COSV56606935; called by muse, mutect2
- BLOC1S6 | c.397A>T p.K133* | Nonsense Mutation (SNP) | VAF 14/456 reads (3%) | called by muse, mutect2
- IGHA2 | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- OR4C13 | c.706T>A p.S236T | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZC3H18 | c.1205_1206+2del p.X402_splice | Splice Site (DEL) | VAF 12/125 reads (10%) | called by mutect2, pindel
- CDH1 | c.987C>T p.V329= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV99932710; called by muse, mutect2
- DOP1A | c.5166T>C p.T1722= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as COSV99383222; called by muse, mutect2
- ERGIC2 | c.339A>G p.V113= | Silent (SNP) | VAF 8/145 reads (6%) | catalogued as COSV100792025; called by muse, mutect2
- GNPTAB | c.1716C>T p.A572= | Silent (SNP) | VAF 11/158 reads (7%) | catalogued as COSV100172550; called by muse, mutect2
- IPO4 | c.2691G>A p.V897= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100269351; called by muse, mutect2
- LAMB3 | c.2310G>A p.L770= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as COSV100620589; called by muse, mutect2
- PLCZ1 | c.1500A>G p.S500= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV99857202; called by muse, mutect2
- PRRC2A | c.1137C>T p.N379= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV100784644; called by muse, mutect2
- RANBP2 | c.5949C>T p.Y1983= | Silent (SNP) | VAF 13/341 reads (4%) | catalogued as rs1384565914, COSV99313651; called by muse, mutect2
- SH3PXD2A | c.2625C>T p.S875= (on ENST00000369774 / NM_001365079.1; = p.S847= on NM_014631.2) | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as rs1018712885, COSV100280602; called by muse, mutect2
- SIAH2 | c.228G>A p.S76= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV100469511; called by muse, mutect2
- SMPDL3A | c.207T>C p.N69= | Silent (SNP) | VAF 10/238 reads (4%) | catalogued as COSV100868747; called by muse, mutect2
- TET1 | c.3378A>G p.K1126= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as rs1276550897, COSV101019109; called by muse, mutect2
- VIT | c.1362C>T p.N454= (on ENST00000389975 / NM_001177969.1; = p.N469= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as rs1246729509, COSV64896300; called by muse, mutect2
